Gene-level copy-number profile of tumor specimen TCGA-WE-A8ZN-06A from TCGA case TCGA-WE-A8ZN, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 60.3 years (22,034 days).
Specimen TCGA-WE-A8ZN-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.aa9eddf9-e064-46fe-bed4-5fe6e340235d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WE-A8ZN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2c9a2474-2a74-4f4d-939f-07ace6057333

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 159; copy number 1: 3,812; copy number 2: 52,415; copy number 3: 2,894; copy number 4: 66; copy number 5: 350; copy number 6: 47; copy number 9: 20; copy number 10: 36; copy number 13: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WE-A8ZN-06A-11D-A371-01): tumor purity 0.51, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 159 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:11,618,496–15,146,401, 42 genes (within-gene range 0–1): AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1.
- chr9:15,464,066–17,797,124, 23 genes (within-gene range 0–1): PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P, CCDC171, HMGN2P16, RNU6-14P, C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1, SH3GL2, PABPC1P11.
- chr9:20,341,669–26,644,595, 90 genes (broad region; genes not listed).
- chr9:27,948,078–28,670,286, 4 genes: LINGO2, AL451124.1, AL445526.1, KCTD10P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 467 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:61,102,489–61,511,018, 23 genes, copy number 5: CD5, VPS37C, AP000437.1, PGA3, PGA4, AP003037.1, PGA5, VWCE, DDB1, TKFC, CYB561A3, AP003108.3, TMEM138, TMEM216, CPSF7, AP003108.4, AP003108.2, SDHAF2, RN7SL23P, PPP1R32, AP003108.1, MIR4488, LRRC10B.
- chr11:65,916,810–66,843,516, 63 genes, copy number 5 (broad region; genes not listed).
- chr11:68,891,276–70,015,815, 32 genes, copy number 6: MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2.
- chr11:70,467,856–71,252,577, 1 gene, copy number 5 (within-gene range 3–5): SHANK2.
- chr11:70,626,441–77,474,635, 234 genes, copy number 5–13 (within-gene range 4–13) (broad region; genes not listed).
- chr11:79,604,967–81,556,425, 12 genes, copy number 5: AP001978.1, AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25.
- chr11:85,452,282–86,952,910, 34 genes, copy number 6–9 (within-gene range 4–9): AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3, AP003059.1, AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P.
- chr11:100,336,856–100,337,625, 1 gene, copy number 6: RPA2P3.
- chr11:101,451,564–101,872,562, 1 gene, copy number 5 (within-gene range 1–5): TRPC6.
- chr11:101,584,295–103,479,863, 50 genes, copy number 5: AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1.
- chr11:117,800,844–118,176,639, 12 genes, copy number 5 (within-gene range 1–5): FXYD2, AP000757.2, FXYD6-FXYD2, AP000757.1, FXYD6, TMPRSS13, IL10RA, SMIM35, RN7SL828P, TMPRSS4, SCN4B, SCN2B.
- chr11:118,226,690–118,266,817, 3 genes, copy number 5: MPZL3, MPZL2, AP002800.1.
- chr11:120,867,933–120,894,797, 1 gene, copy number 5 (within-gene range 4–5): AP004147.1.

Autosomal genes at a single copy (total copy number 1): 1,397. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
